Somatic mutation profile of tumor specimen HCM-CSHL-0085-C24-06A (aliquot HCM-CSHL-0085-C24-06A-11D-A78L-36) from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4485d01-736b-4e1a-9cba-6226ecd0d9b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0085-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0085-C24-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6159e0b1-04b6-4ee6-8bdb-2d007aebd45a

The open-access MAF lists 96 somatic variants for this specimen: 62 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 28, Nonsense Mutation 3, Splice Region 3, Intron 2, RNA 2, 5'UTR 1, Translation Start Site 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 45/341 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV51552966; called by muse, mutect2, varscan2
- ADGRB1 | c.2202G>A p.A734= | Splice Region (SNP) | VAF 17/124 reads (14%) | catalogued as rs753558928; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2, varscan2
- AIM2 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100931079; called by muse, mutect2
- ANK2 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 69/592 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as rs1238418730; called by muse, mutect2, varscan2
- ARID2 | c.1352del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as COSV57600163; called by mutect2, pindel, varscan2
- CALHM2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as rs377104588; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by muse, mutect2, varscan2
- EPHA1 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767930814; called by muse, mutect2, varscan2
- ESPNL | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs927691376; called by muse, mutect2, varscan2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2
- HCAR3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368546949; called by muse, mutect2
- HOGA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754634699, COSV65706481; called by muse, mutect2, varscan2
- ICAM5 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55748939; called by muse, mutect2
- ITCH | c.1970C>T p.T657M (on ENST00000262650 / NM_001257137.3; = p.T616M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445655265, COSV52933847; called by muse, mutect2
- LRRTM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV69142997; called by muse, mutect2, varscan2
- MCRIP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754717613; called by muse, mutect2
- OR2J2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755187820; called by muse, mutect2
- OR4A16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV59042819; called by muse, mutect2, varscan2
- P2RY14 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56391075; called by muse, mutect2
- PARP10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs782649313, COSV57299228; called by muse, varscan2
- PCDHB15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1554292027; called by muse, mutect2, varscan2
- PLEKHM3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 34/149 reads (23%) | catalogued as rs1447181721; called by muse, mutect2, varscan2
- PLXND1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554042254; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, mutect2, varscan2
- RAD50 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1372866109; called by muse, mutect2
- RYR3 | c.13120C>T p.R4374W (on ENST00000389232; = p.R4375W on NM_001036.6) | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759909362, COSV66778249; called by muse, mutect2
- SIRPB1 | c.432C>T p.R144= | Splice Region (SNP) | VAF 26/382 reads (7%) | catalogued as rs200840558, COSV53537445; called by muse, mutect2
- SRD5A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014835; called by muse, mutect2, varscan2
- TDRD9 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs142470189; called by muse, mutect2, varscan2
- TPTE2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV55023847; called by muse, mutect2, varscan2
- TTN | c.31129G>A p.A10377T (on ENST00000591111; = p.A9450T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | PolyPhen benign (0.025); catalogued as rs756672871; called by muse, mutect2, varscan2
- UNC5C | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142722408; called by muse, mutect2
- ZSCAN9 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV99356463; called by muse, mutect2
- ACO1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ANK2 | c.2694-4C>T | Splice Region (SNP) | VAF 37/401 reads (9%) | called by muse, mutect2
- AP5M1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 65/292 reads (22%) | called by muse, mutect2, varscan2
- ARID1A | c.4984A>T p.K1662* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- CDH12 | c.1967A>C p.N656T | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CUL4A | c.1858+1G>T p.X620_splice (on ENST00000375440 / NM_001008895.4; = p.X520_splice on NM_003589.3) | Splice Site (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- DHX33 | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ESF1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR75 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HMCN2 | c.12859G>C p.E4287Q | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2
- IPO7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KNDC1 | c.3543G>C p.R1181S | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- NRDC | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKG1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- PIP5K1C | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 47/549 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- PLK2 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPP1R3A | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRKDC | c.1068_1070del p.N356del | In Frame Del (DEL) | VAF 18/127 reads (14%) | called by pindel, varscan2
- PTGER3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, varscan2
- SF3A3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC6A4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.56612A>C p.K18871T (on ENST00000591111; = p.K11447T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | PolyPhen possibly damaging (0.856); called by muse, mutect2
- UGT2B15 | c.220T>G p.L74V | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- XYLT2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZDHHC6 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF385D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/158 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- AKIRIN1 | c.393A>G p.T131= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs1298893257; called by muse, mutect2, varscan2
- ALPK2 | c.3045C>T p.T1015= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs541753586; called by muse, mutect2
- ANKRD1 | c.657C>A p.L219= | Silent (SNP) | VAF 54/587 reads (9%) | catalogued as COSV100865362; called by muse, mutect2
- ARPP21 | c.1317A>G p.A439= | Silent (SNP) | VAF 15/334 reads (4%) | catalogued as COSV51806064; called by muse, mutect2
- ASCL3 | c.18C>T p.G6= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV100366920; called by muse, mutect2
- C3AR1 | c.183C>T p.F61= | Silent (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- CCDC160 | c.582G>A p.T194= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs751796060, COSV66251327; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 54/540 reads (10%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2
- DDX3X | c.228T>C p.D76= (on ENST00000399959; = p.D77= on NM_001356.5) | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2256G>T p.L752= (on ENST00000400246; = p.L821= on NM_014662.5) | Silent (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- FAM209A | c.447G>A p.K149= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- FAT4 | c.10095A>C p.R3365= | Silent (SNP) | VAF 25/261 reads (10%) | called by muse, mutect2
- GRIN1 | c.114C>T p.H38= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as rs1241572680, COSV59300354; called by muse, mutect2
- HDAC7 | c.1980T>C p.G660= (on ENST00000427332; = p.G699= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- HOXD4 | c.90C>T p.G30= | Silent (SNP) | VAF 10/279 reads (4%) | catalogued as rs924937832, COSV60460000; called by muse, mutect2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 56/662 reads (8%) | catalogued as rs368264920; called by muse, mutect2
- KRT5 | c.75G>A p.P25= | Silent (SNP) | VAF 21/183 reads (11%) | catalogued as rs572849401; called by muse, mutect2, varscan2
- MDGA2 | c.372A>T p.G124= | Silent (SNP) | VAF 40/223 reads (18%) | called by muse, mutect2, varscan2
- NPRL2 | c.354C>T p.F118= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as rs928016141, COSV51600078; called by muse, mutect2
- OLIG2 | c.168C>T p.R56= | Silent (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- OR56B4 | c.810G>A p.E270= | Silent (SNP) | VAF 79/370 reads (21%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2868C>T p.F956= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- SOX21 | c.57G>A p.S19= | Silent (SNP) | VAF 27/705 reads (4%) | catalogued as COSV65375414; called by muse, mutect2
- SYDE1 | c.819C>T p.Y273= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1413962871; called by muse, mutect2, varscan2
- TFEB | c.37C>A p.R13= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV57824244; called by muse, mutect2
- TRPM8 | c.2286G>A p.S762= | Silent (SNP) | VAF 101/531 reads (19%) | catalogued as rs199933698, COSV61222637; called by muse, mutect2, varscan2
- UBE3A | c.1372C>T p.L458= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- ZWILCH | c.1020C>T p.F340= | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as rs769354705; called by muse, mutect2, varscan2
- FOXP2 | c.168+36459C>T | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- LEPR | c.-120C>G | 5'UTR (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2
- OSBPL2 | chr20:62233193 C>T | 5'Flank (SNP) | VAF 14/198 reads (7%) | catalogued as rs375508203; called by muse, mutect2
- PARGP1 | n.1966C>T | RNA (SNP) | VAF 18/287 reads (6%) | catalogued as rs1374034744; called by muse, mutect2
- UBTFL2 | n.483A>G | RNA (SNP) | VAF 97/545 reads (18%) | catalogued as rs1433232626; called by muse, mutect2, varscan2
- ZNF589 | c.97-3971G>A | Intron (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
